Somatic mutation profile of tumor specimen 0DP6HX from CCDI case PBCDCC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 1.9 years (707 days).
Specimen 0DP6HX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc34a037-4b5e-427d-83ec-8afb0d456677.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP6HK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ca39ad0-62cb-4c8f-a820-794534fde996

The open-access MAF lists 3 somatic variants for this specimen: 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRODH2 | c.1422A>T p.A474= (on ENST00000301175; = p.A398= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 24/208 reads (12%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 9/222 reads (4%) | called by muse, mutect2
- KLF9 | c.-60C>T | 5'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
